Gene-level copy-number profile of tumor specimen TCGA-04-1648-01A from TCGA case TCGA-04-1648, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G2; Age at diagnosis: 57.8 years (21,113 days).
Specimen TCGA-04-1648-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.634da42b-ae78-42e0-8115-37a735e4e057.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-04-1648-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/a20bd2a7-ec2c-4bfd-9f4c-e7cf8a354d1f

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 935; copy number 2: 16,750; copy number 3: 2,950; copy number 4: 36,484; copy number 5: 1,954; copy number 6: 549; copy number 7: 34; copy number 9: 41; copy number 10: 58; copy number 12: 63.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-04-1648-01A-01D-0577-01): tumor purity 0.8, ploidy 1.75, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 162 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr16:8,537,605–9,156,881, 23 genes, copy number 9 (within-gene range 5–9): TMEM114, AC138420.1, METTL22, AC007224.2, ABAT, RN7SL743P, RNU7-63P, AC007224.1, TMEM186, PMM2, AC012173.1, AC022167.2, CARHSP1, AC022167.1, AC022167.4, LITAFD, USP7, AC022167.3, AC087190.2, C16orf72, AC087190.3, AC087190.1, RPL21P119.
- chr16:15,594,387–16,223,522, 18 genes, copy number 9 (within-gene range 6–9): MARF1, AC026401.1, MIR6506, NDE1, MIR484, AC026401.2, AC026401.3, MYH11, AF001548.2, AF001548.1, AF001548.3, CEP20, RNU6-213P, AC130651.1, RPL15P20, ABCC1, RPL17P40, ABCC6.
- chr17:81,965,632–83,095,122, 63 genes, copy number 12 (broad region; genes not listed).
- chr22:29,419,155–30,627,271, 58 genes, copy number 10 (within-gene range 1–10): AC000041.1, RFPL4AP6, RFPL1S, RFPL1, NEFH, AC000035.1, THOC5, AC005529.1, NIPSNAP1, NF2, RPEP4, AC004882.1, AC004882.2, CABP7, ZMAT5, Y_RNA, AC004882.3, UQCR10, ASCC2, MTMR3, RNU6-331P, AC003681.1, MIR6818, HORMAD2-AS1, CNN2P1, HORMAD2, AC003071.1, RPS3AP51, AC002378.1, LIF-AS1, LIF, AC004264.1, OSM, AC004264.2, CASTOR1, AC004997.1, TBC1D10A, SF3A1, CCDC157, RNF215, SEC14L2, AC004832.3, AC004832.5, RNU6-564P, AC004832.4, MTFP1, AC004832.6, AC004832.2, SEC14L3, AC004832.1, SDC4P, SEC14L4, SEC14L6, SIRPAP1, GAL3ST1, PES1, AC005006.1, TCN2.

Autosomal genes at a single copy (total copy number 1): 935. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
